Somatic mutation profile of tumor specimen TCGA-A3-3323-01A (aliquot TCGA-A3-3323-01A-01D-0966-08) from TCGA case TCGA-A3-3323, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 53.3 years (19,456 days).
Specimen TCGA-A3-3323-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a370255a-e08c-4ceb-920e-ede7f72d505b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A3-3323-11A (Solid Tissue Normal), aliquot TCGA-A3-3323-11A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a075e7b-501f-43ca-90d0-47b9b3058739

The open-access MAF lists 51 somatic variants for this specimen: 42 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Nonsense Mutation 7, Frame Shift Del 7, Frame Shift Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARAP3 | c.1580G>T p.C527F | Missense Mutation (SNP) | VAF 100/409 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53348542; called by muse, mutect2, varscan2
- CIT | c.2327C>T p.S776F | Missense Mutation (SNP) | VAF 78/354 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV55876700; called by muse, mutect2, varscan2
- DNAJB4 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.259); catalogued as COSV66131914; called by muse, mutect2, varscan2
- GBP1 | c.824G>A p.S275N | Missense Mutation (SNP) | VAF 100/385 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs374475528; called by muse, mutect2, varscan2
- GOLGA5 | c.2038A>G p.I680V | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.562); catalogued as rs373869475; called by muse, mutect2, varscan2
- HECW1 | c.1300G>T p.G434* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV67839761; called by muse, mutect2, varscan2
- KLHL25 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs142937016; called by muse, mutect2, varscan2
- PSAT1 | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs759482379; called by muse, mutect2, varscan2
- SERPINB13 | c.60del p.T22Qfs*14 | Frame Shift Del (DEL) | VAF 37/170 reads (22%) | catalogued as COSV54029153; called by mutect2, pindel, varscan2
- SLC29A4 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV51875795, COSV51876836; called by muse, mutect2, varscan2
- SLC4A3 | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.639); catalogued as rs150796797; called by muse, mutect2, varscan2
- TSPAN1 | c.625C>T p.R209* | Nonsense Mutation (SNP) | VAF 20/492 reads (4%) | catalogued as COSV64340381; called by muse, mutect2
- ZNF653 | c.1466A>G p.N489S | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1337519168, COSV99542092; called by muse, mutect2, varscan2
- AFG3L2 | c.482T>A p.L161* | Nonsense Mutation (SNP) | VAF 53/193 reads (27%) | called by muse, mutect2, varscan2
- AP3M2 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARHGEF25 | c.1597G>T p.E533* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | called by muse, mutect2, varscan2
- ATP10D | c.1146C>G p.V382= | Splice Region (SNP) | VAF 40/218 reads (18%) | called by muse, mutect2, varscan2
- C1orf198 | c.374G>A p.W125* | Nonsense Mutation (SNP) | VAF 34/201 reads (17%) | called by muse, mutect2, varscan2
- CCNB2 | c.550C>T p.Q184* | Nonsense Mutation (SNP) | VAF 98/394 reads (25%) | called by muse, mutect2, varscan2
- CRYM | c.849C>A p.H283Q | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH10 | c.13571G>C p.G4524A (on ENST00000409039; = p.G4463A on NM_207437.3) | Missense Mutation (SNP) | VAF 75/304 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ECI2 | c.1132G>A p.D378N (on ENST00000380118 / NM_206836.3; = p.D348N on NM_006117.2) | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.156); called by muse, mutect2
- HELZ2 | c.4064del p.D1355Vfs*86 (on ENST00000467148 / NM_001037335.2; = p.D786Vfs*86 on NM_033405.3) | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel
- HSPA9 | c.928G>T p.E310* | Nonsense Mutation (SNP) | VAF 111/419 reads (26%) | called by muse, mutect2, varscan2
- KDM5C | c.1298del p.E433Gfs*4 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | called by mutect2, pindel, varscan2
- MCM6 | c.88T>A p.F30I | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPS24 | c.438T>G p.F146L | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NKD2 | c.163A>C p.K55Q | Missense Mutation (SNP) | VAF 54/234 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.207); called by muse, varscan2
- NRROS | c.256_262del p.L86Cfs*57 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, pindel, varscan2
- OLFML3 | c.517G>A p.D173N | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PBRM1 | c.714+2T>C p.X238_splice | Splice Site (SNP) | VAF 45/144 reads (31%) | called by muse, mutect2, varscan2
- PTPRC | c.1617C>A p.F539L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RPL4 | c.365A>T p.Y122F | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- SCN5A | c.2873A>G p.N958S | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- SLC39A7 | c.279_285del p.H94Tfs*49 | Frame Shift Del (DEL) | VAF 26/131 reads (20%) | called by mutect2, pindel, varscan2
- SSMEM1 | c.22T>G p.F8V | Missense Mutation (SNP) | VAF 77/339 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPM6 | c.1736A>T p.K579M | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TRPV5 | c.1728del p.M577* | Frame Shift Del (DEL) | VAF 30/150 reads (20%) | called by mutect2, pindel, varscan2
- TTYH1 | c.1070C>G p.T357R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- USH2A | c.8613dup p.D2872Rfs*17 | Frame Shift Ins (INS) | VAF 81/426 reads (19%) | called by mutect2, pindel, varscan2
- ZFP82 | c.950_957del p.K317Ifs*7 | Frame Shift Del (DEL) | VAF 61/239 reads (26%) | called by mutect2, pindel, varscan2
- ZNF800 | c.1129C>T p.H377Y | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CES1 | c.1035C>T p.P345= | Silent (SNP) | VAF 7/200 reads (4%) | called by muse, mutect2
- ITGA5 | c.1338G>C p.L446= | Silent (SNP) | VAF 7/96 reads (7%) | catalogued as COSV53220479; called by muse, mutect2
- MBD6 | c.1842T>G p.P614= | Silent (SNP) | VAF 68/280 reads (24%) | called by muse, mutect2, varscan2
- MIGA2 | c.177C>T p.A59= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs994284425; called by muse, mutect2, varscan2
- MUC17 | c.12177T>G p.S4059= | Silent (SNP) | VAF 59/316 reads (19%) | called by muse, mutect2, varscan2
- OR56A3 | c.108C>T p.S36= | Silent (SNP) | VAF 8/194 reads (4%) | called by muse, mutect2
- POPDC2 | c.333C>T p.L111= | Silent (SNP) | VAF 78/171 reads (46%) | called by muse, mutect2, varscan2
- RELN | c.9702C>A p.L3234= | Silent (SNP) | VAF 17/60 reads (28%) | called by muse, mutect2, varscan2
- USP22 | c.246C>T p.F82= | Silent (SNP) | VAF 54/158 reads (34%) | catalogued as rs752989047; called by muse, mutect2, varscan2
